Surgical pathology report (de-identified scan), TCGA case TCGA-FG-8181, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-8181-01A (Primary Tumor).

[page 1 of 4]
Result InformationStatus
EditedProvider Status
Ordered

Observation Date and Time

Entry Date

Result Narrative

(NOTE)

Surgical Pathology Report

Patient Name:
Accession #:
Med. Rec #:
Submitting Physician:

--- Clinical History ---

Malignant neoplasm of frontal lobe of brain [191.1]. Medical History:
GERD (gastroesophageal reflux disease). Optic nerve edema.

ADDENDA:

Addendum added:

Addendum added:

---Final Pathologic Diagnosis---

- A. Left frontal tumor, biopsy:
- Slides have been referred to [REDACTED] for review and diagnosis. An addendum will follow.
- B. Left frontal tumor, excision:
- Slides have been referred to [REDACTED] for review and diagnosis. An addendum will follow.
- C. Left frontal tumor, excision:
- Slides have been referred to [REDACTED] for review and diagnosis. An addendum will follow.

Electronically Signed By

---Addendum Report---

Addendum

Status: Signed Out

[page 2 of 4]
See below

Since the pathologists of [REDACTED] specialists in neuropathology and were the locum tenens on this case during my absence, I offer no professional opinion on this case except to indicate that the interpretation of the pathologist of [REDACTED] been faithfully transferred to this addendum. The original consultation report is on file in Surgical Pathology. The following is the text of their report.

Report received from:

[REDACTED]

Surgical Pathology
Consult Service

[REDACTED]

INTERPRETATION AND DIAGNOSIS:

1) LT FRONTAL TUMOR [REDACTED] ANAPLASTIC INFILTRATING GLIOMA (WHO GRADE III). SEE COMMENT.

COMMENT: Histologic sections demonstrate an infiltrating glial neoplasm with increased mitotic activity (up to 5 per 10 high power fields). Areas of the tumor demonstrate cells with numerous cytoplasmic processes and nuclear pleomorphism, while others contain round cells with micronucleoli and halos. Immunohistochemical stains performed at [REDACTED] demonstrate strong p53 labeling. MIB-1 labeling index is moderate. Molecular SNP array studies are negative for 1p/19q loss. The findings support a diagnosis of anaplastic infiltrating glioma. Given the variable cytologic features (pleomorphic and round cells) the tumor may be interpreted as an oligoastrocytoma.

[REDACTED]

*Electronic signature

Some stains/tests used in arriving at the diagnosis were performed here using reagents that have not been cleared or approved by the US Food and Drug Administration. These were developed and their performance determined by the [REDACTED] Medical Laboratories. Their use does not require FDA approval.

GROSS DESCRIPTION

PART #1: LT FRONTAL TUMOR [REDACTED]
Resident Pathologist: NONE ASSIGNED

Received 14 slides [REDACTED] (AF1, AF2P, AF, B1-B5, C1-C6) from [REDACTED]
[REDACTED]

[page 3 of 4]
2/8/12, Received 8 unstained slides [REDACTED] B4).

2/24/12, Received 5 additional unstained slides [REDACTED] B4).

End of Report.

[REDACTED] Electronically Signed Out By***

Addendum

Status: Signed Out

Since the pathologists of [REDACTED] are specialists in neuropathology and were the locum tenens on this case during my absence, I offer no professional opinion on this case except to indicate that the interpretation of the pathologist of [REDACTED] has been faithfully transferred to this addendum. The original consultation report is on file in Surgical Pathology. The following is the text of their report.

Addendum from:

ADDENDUM [REDACTED]

Synaptophysin and Neu-N immunostains performed at [REDACTED] highlight non-neoplastic brain parenchyma.

[REDACTED]

*Electronic signature

Some stains/tests used in arriving at the diagnosis were performed here using reagents that have not been cleared or approved by the US Food and Drug Administration. These were developed and their performance determined by the [REDACTED] Laboratories. Their use does not require FDA approval.

[REDACTED] Electronically Signed Out By***

[page 4 of 4]
---INTRAOPERATIVE CONSULTATION DIAGNOSIS:---

AF1. Left frontal tumor (Frozen section performed):

- Consistent with glial neoplasm, possible oligo.

Note: Called to Dr. [REDACTED]

Examining pathologist:

---MICROSCOPIC:---

A microscopic examination was not performed.

---SPECIMEN(S) RECEIVED:---

NBX

A: Neuropath, Brain, Bx

B: Neuropath Reg

C: Neuropath Reg

---GROSS DESCRIPTION:---

The specimens are received in two properly labeled containers with the patient's name and accession number, one of which is a frozen section.

A. The specimen is designated "left frontal tumor" and consists of a 0.7 x 0.3 x 0.3 cm portion of tissue. A frozen section was performed and cassette AF1 is resubmitted as received. [REDACTED]

B. The specimen is designated "left frontal tumor" and consists of a 3.9 x 3.8 x 2.8 cm gray-tan to pink soft tumor with focal areas of hemorrhage. [REDACTED]

Summary of Cassettes: B1-5, tumor

C. The specimen is designated "left frontal tumor" and consists of a 5.5 x 5.0 x 1.7 cm aggregate of extremely soft white-tan to pink-tan, slightly mucinous soft tissue. The cut surface is pink-tan to white-tan and gelatinous. RS6

Lab Use Only: [REDACTED]

Lab Use Only: [REDACTED]

Gross description by: [REDACTED]

This result is currently not released to [REDACTED]

Patient Care Team

	Relationship	Specialty	Notifications	Start	End
[REDACTED]	PCP - General	Family Medicine		[REDACTED]	

Source: NCI Genomic Data Commons file 6658e4b9-f09e-4923-8519-7b14e8f93423 (TCGA-FG-8181.6B2E8993-F8A8-400A-BC49-B283CA7221FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).